Somatic mutation profile of tumor specimen TCGA-X7-A8DF-01A (aliquot TCGA-X7-A8DF-01A-11D-A423-09) from TCGA case TCGA-X7-A8DF, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 40.5 years (14,804 days).
Specimen TCGA-X7-A8DF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61a8b73d-0d6c-4dd0-b45f-1ffcbc479f45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8DF-10A (Blood Derived Normal), aliquot TCGA-X7-A8DF-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ce7efe6-11cd-4b85-81d0-d5e5308287db

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 35/382 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
